Somatic mutation profile of tumor specimen TCGA-EL-A3CY-01A (aliquot TCGA-EL-A3CY-01A-11D-A19J-08) from TCGA case TCGA-EL-A3CY, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 28.5 years (10,423 days).
Specimen TCGA-EL-A3CY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb461a17-1542-4599-b965-afaa91fb923c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3CY-10A (Blood Derived Normal), aliquot TCGA-EL-A3CY-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87119ead-b394-45d3-a1ad-1ea806d5b5fa

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FNBP4 | c.2668C>T p.P890S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV55452170; called by muse, mutect2
- SEC23A | c.441G>A p.L147= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV56978779; called by muse, mutect2
